TCGA case TCGA-A7-A0DC — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Christiana Healthcare. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/cb9f5e50-f49d-4899-8895-9367afcc1015

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Year of birth: 1946; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Age at diagnosis: 63.8 years (23,294 days); Year of diagnosis: 2009; Days to diagnosis: 0 days; AJCC pathologic T: T1c; AJCC pathologic N: N0 (i-); AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 906 days (2.5 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A7-A0DC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 200 mg.
  Slide TCGA-A7-A0DC-01A-01-BS1: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 29; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-A7-A0DC-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-A7-A0DC-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
  Slide TCGA-A7-A0DC-01B-03-BS3: Section location: Top; Percent tumor cells: 20; Percent tumor nuclei: 60; Percent normal cells: 3; Percent necrosis: 3; Percent stromal cells: 74; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
  Slide TCGA-A7-A0DC-01B-04-BS4: Section location: Bottom; Percent tumor cells: 12; Percent tumor nuclei: 60; Percent normal cells: 4; Percent necrosis: 1; Percent stromal cells: 83; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-A7-A0DC-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A7-A0DC-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-A7-A0DC-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 470 mg.
  Slide TCGA-A7-A0DC-11A-04-TS4: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 100; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined count: 3; Axillary staging method: Sentinel lymph node biopsy plus axillary dissection; Surgical procedure first: Simple Mastectomy; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); Pr status by IHC: Negative; Micromet detection by IHC: Yes; Her2 IHC score: 1+; Margin status: Negative; Method initial path diagnosis: Tumor resection; Er status by IHC: Positive; Her2 status by IHC: Negative; Lymph nodes examined IHC count: 0; Lymph nodes examined he count: 0; Prospective collection: Yes; Retrospective collection: No; Er status IHC Percent Positive: 90-99%; Pr status IHC percent positive: <10%.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Right Upper Outer Quadrant; Anatomic organ subdivision: Right.
- Follow-up form 2: Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Drug treatment 1: Regimen number: 1; Total dose: 558; Pharmaceutical treatment total dose units: mg; Prescribed dose: 69-71; Pharmaceutical treatment dose units: mg; Pharma adjuvant cycles count: 8; Days from index date to pharmaceutical treatment started: 77; Days from index date to pharmaceutical treatment ended: 231; Pharmaceutical therapy drug name: Methotrexate; Therapy regimen: Adjuvant; Pharmaceutical treatment ongoing indicator: No.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 1; Total dose: 8346; Pharmaceutical treatment total dose units: mg; Prescribed dose: 1032-1062; Pharmaceutical treatment dose units: mg; Pharma adjuvant cycles count: 8; Days from index date to pharmaceutical treatment started: 77; Days from index date to pharmaceutical treatment ended: 231; Pharmaceutical therapy drug name: Fluorouracil; Therapy regimen: Adjuvant; Pharmaceutical treatment ongoing indicator: No.
- Drug treatment 3: Regimen number: 1; Total dose: 8346; Pharmaceutical treatment total dose units: mg; Prescribed dose: 1032-1062; Pharmaceutical treatment dose units: mg; Pharma adjuvant cycles count: 8; Days from index date to pharmaceutical treatment started: 77; Days from index date to pharmaceutical treatment ended: 231; Pharmaceutical therapy drug name: Cyclophosphamide; Therapy regimen: Adjuvant; Pharmaceutical treatment ongoing indicator: No.
- Drug treatment 4: Regimen number: 1; Total dose: 170; Pharmaceutical treatment total dose units: mg; Prescribed dose: 1; Pharmaceutical treatment dose units: mg; Days from index date to pharmaceutical treatment started: 264; Pharmaceutical therapy drug name: Arimidex; Therapy regimen: Adjuvant; Pharmaceutical treatment ongoing indicator: Yes.
- Drug treatment 4, Therapy types: Pharmaceutical therapy type: Hormone Therapy.
- Drug treatment 4, Route of administrations: Route of administration: PO.
- Drug treatment 5: Regimen number: 1; Total dose: 245; Pharmaceutical treatment total dose units: mg; Prescribed dose: 1; Pharmaceutical treatment dose units: mg; Pharma adjuvant cycles count: 245; Days from index date to pharmaceutical treatment started: 264; Days from index date to pharmaceutical treatment ended: 509; Pharmaceutical therapy drug name: Arimidex; Therapy regimen: Adjuvant; Pharmaceutical treatment ongoing indicator: No.
- Drug treatment 6: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 510; Pharmaceutical therapy drug name: Tamoxifen; Pharmaceutical treatment ongoing indicator: No.
- Radiation treatment: Days from index date to radiation therapy started: 309; Days from index date to radiation therapy ended: 351; Radiation therapy type: External beam; Radiation total dose: 5040; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 28; Radiation therapy site: Primary Tumor Field; Therapy regimen: Adjuvant; Radiation therapy ongoing indicator: No; Course number: 1.

GDC annotations on this case (curator notes; quoted as recorded):
- Item does not meet study protocol: Tumor is DCIS and not invasive which is required by the TCGA BRCA study.

The TCGA Pan-Cancer Clinical Data Resource (Liu et al., Cell 2018) lists this case as redacted by TCGA at the time of its curation; its follow-up endpoints are therefore not restated here.
